Somatic mutation profile of tumor specimen C3L-02408-02 (aliquot CPT0111720009) from CPTAC case C3L-02408, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 60.8 years (22,191 days).
Specimen C3L-02408-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f475d15b-6ad3-4f73-9db8-5f0d5781e52f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02408-31 (Blood Derived Normal), aliquot CPT0112800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1e9071b-fcdc-423d-8a24-464ef1da1099

The open-access MAF lists 55 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Nonsense Mutation 3, Intron 2, 5'Flank 1, In Frame Ins 1, Splice Site 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 178/444 reads (40%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.4072C>T p.R1358W | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs778082183, COSV62321494; called by muse, mutect2, varscan2
- ADAD2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.072); catalogued as rs548863737, COSV99235836; called by muse, mutect2, varscan2
- ARID1A | c.5063T>G p.L1688* | Nonsense Mutation (SNP) | VAF 66/331 reads (20%) | catalogued as COSV104411776, COSV61384281; called by muse, mutect2, varscan2
- C10orf71 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 76/527 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs757331659; called by muse, mutect2, varscan2
- CDC20B | c.568T>C p.C190R | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765619994; called by muse, mutect2, varscan2
- CFAP65 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs190844624, COSV99838357; called by muse, mutect2, varscan2
- CLUH | c.826C>T p.R276C (on ENST00000435359; = p.R314C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs200260191; called by muse, mutect2, varscan2
- EBF3 | c.871G>A p.G291R (on ENST00000355311 / NM_001375392.1; = p.G282R on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/390 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62479941; called by muse, mutect2, varscan2
- EPHB1 | c.1321C>A p.H441N | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as COSV101214656; called by muse, mutect2
- GOLT1A | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs778528625, COSV57643351; called by muse, mutect2, varscan2
- MITD1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs772570636, COSV99175533; called by muse, mutect2, varscan2
- MTM1 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs782468721, COSV60335430; called by muse, mutect2
- OGDHL | c.2486G>A p.R829H | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774307179; called by muse, mutect2, varscan2
- PCDH11X | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 19/592 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV53447097; called by muse, mutect2
- PIK3R1 | c.1702_1704dup p.P568dup (on ENST00000521381 / NM_181523.3; = p.P298dup on NM_181504.4) | In Frame Ins (INS) | VAF 22/127 reads (17%) | catalogued as COSV99073788; called by mutect2, pindel, varscan2
- RNASEL | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs554935584; called by muse, mutect2, varscan2
- SPTLC3 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs371553499; called by muse, mutect2, varscan2
- TAFA5 | c.184G>A p.A62T (on ENST00000402357 / NM_001082967.3; = p.A55T on NM_015381.7) | Missense Mutation (SNP) | VAF 53/411 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs777360580, COSV60970759; called by muse, mutect2, varscan2
- TRIML2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1464457758, COSV58720914; called by muse, mutect2, varscan2
- USP31 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs760172401; called by muse, mutect2, varscan2
- WWC3 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as rs755168163, COSV66507745; called by muse, mutect2
- AHR | c.1768A>C p.S590R | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- AKAP9 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- B4GALNT3 | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CLDN1 | c.446A>T p.Y149F | Missense Mutation (SNP) | VAF 23/351 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.313); called by muse, mutect2
- COL4A2 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXA2 | c.629C>G p.S210W (on ENST00000377115 / NM_153675.3; = p.S216W on NM_021784.5) | Missense Mutation (SNP) | VAF 74/449 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IRX2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 98/425 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LPCAT2 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.021); called by muse, mutect2
- MRC1 | c.1414T>C p.Y472H | Missense Mutation (SNP) | VAF 19/697 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- NCBP1 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- SCUBE3 | c.2753-2A>C p.X918_splice | Splice Site (SNP) | VAF 14/163 reads (9%) | called by muse, mutect2
- SLC5A10 | c.1630G>A p.E544K (on ENST00000395645 / NM_001042450.4; = p.E560K on NM_152351.5) | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS1 | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPAG5 | c.2417C>A p.A806E | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ST8SIA3 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 31/203 reads (15%) | PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- TMCO6 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAG3 | c.1725G>A p.P575= | Silent (SNP) | VAF 40/531 reads (8%) | catalogued as rs772087416; ClinVar: likely benign; called by muse, mutect2
- DYRK4 | c.1479C>G p.V493= | Silent (SNP) | VAF 24/143 reads (17%) | catalogued as COSV99155556; called by muse, mutect2, varscan2
- FANCA | c.1176T>C p.F392= | Silent (SNP) | VAF 85/440 reads (19%) | called by muse, mutect2, varscan2
- GJB2 | c.294G>T p.R98= | Silent (SNP) | VAF 114/582 reads (20%) | called by muse, mutect2, varscan2
- HEXIM1 | c.573C>G p.A191= | Silent (SNP) | VAF 50/239 reads (21%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.555C>A p.A185= | Silent (SNP) | VAF 79/357 reads (22%) | catalogued as rs559467587, COSV99290961; called by muse, mutect2, varscan2
- LSP1 | c.375C>T p.Y125= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as rs577198149, COSV61138036; called by muse, mutect2, varscan2
- NUP210L | c.4668A>G p.A1556= | Silent (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- OR10G3 | c.750C>T p.T250= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as rs757136590, COSV100336149; called by muse, mutect2, varscan2
- R3HDM4 | c.777C>T p.L259= | Silent (SNP) | VAF 42/262 reads (16%) | catalogued as rs1283925896; called by muse, mutect2, varscan2
- TET1 | c.3171A>G p.K1057= | Silent (SNP) | VAF 28/190 reads (15%) | catalogued as COSV65390354; called by muse, mutect2, varscan2
- TLE3 | c.537G>A p.T179= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs368443635; called by muse, mutect2
- ACBD4 | c.*6C>T | 3'UTR (SNP) | VAF 6/104 reads (6%) | catalogued as rs1315862388; called by muse, mutect2
- HACD1 | c.257+1250C>G | Intron (SNP) | VAF 73/195 reads (37%) | called by muse, mutect2, varscan2
- MMGT1 | c.-215T>C | 5'UTR (SNP) | VAF 101/571 reads (18%) | called by muse, mutect2, varscan2
- PPP3CA | chr4:101348707 A>G | 5'Flank (SNP) | VAF 53/227 reads (23%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.5544+95G>T | Intron (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
